Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAN3, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAN3-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

DIAGNOSIS:

RADICAL CYSTOPROSTATECTOMY WITH LYMPH NODE DISSECTION, CONTINENT URINARY RESERVOIR
TO URETHRA AND GASTRIC TUBE PLACEMENT:

RIGHT URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (C):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER / PROSTATE (D):

INTRAOPERATIVE GROSS DIAGNOSIS:

- TUMOR IDENTIFIED, GROSSLY EXTENDING THROUGH BLADDER WALL

BLADDER:

- Pw TSS, 5% glandular, 0% squamous.*
- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (6.5 X 5.5 X 2.0 CM), GRADES 3 AND 4/4, WITH FOCAL SQUAMOID AND GLANDULAR FEATURES
- CARCINOMA GROSSLY AND MICROSCOPICALLY EXTENDING THROUGH BLADDER WALL INTO PERIVESICAL SOFT TISSUE AND TO SUBSEROSA OF PERITONEUM
- LYMPHOVASCULAR INVASION IDENTIFIED
- RANDOM BLADDER MUCOSA EXHIBITING NO EVIDENCE OF UROTHELIAL CARCINOMA IN SITU (FLAT LESION)
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- NO MALIGNANCY IDENTIFIED IN ONE PERIVESICAL LYMPH NODE EXAMINED (0/1)

PROSTATE:

- UNILATERAL PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 7 (4+3), CONFINED TO PROSTATE WITHOUT CAPSULE OR PERIPROSTATIC SOFT TISSUE INVOLVEMENT
- PROSTATIC URETHRA, NO UROTHELIAL DYSPLASIA OR UROTHELIAL MALIGNANCY IDENTIFIED
- BILATERAL SEMINAL VESICLES, FREE OF MALIGNANCY AND SIGNIFICANT HISTOPATHOLOGIC CHANGE
- RESECTION MARGINS, FREE OF MALIGNANCY

LEFT LYMPH NODE OF CLOQUET (E):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT EXTERNAL ILIAC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT OBTURATOR LYMPH NODES (G):

- METASTATIC UROTHELIAL CARCINOMA IDENTIFIED IN ONE OF SEVEN LYMPH NODES EXAMINED (1/7), 0.5 CM GREATEST DIMENSION

*ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder NOS
C67.9
JW 3/26/14*

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

LEFT HYPOGASTRIC LYMPH NODE (H):

- NO MALIGNANCY OR LYMPH NODES IDENTIFIED (0/0) [TOTALLY EMBEDDED]

LEFT COMMON ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT HYPOGASTRIC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT OBTURATOR LYMPH NODES (K):

- METASTATIC UROTHELIAL CARCINOMA IDENTIFIED IN ONE OF 12 LYMPH NODES EXAMINED (1/12), 0.3 CM GREATEST DIMENSION

RIGHT COMMON ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT PRESACRAL LYMPH NODE (M):

- NO MALIGNANCY OR LYMPH NODES IDENTIFIED (0/0) [TOTALLY EMBEDDED]

AORTIC BIFURCATION (N):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT PROXIMAL URETER (O):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (P):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC UROTHELIAL CARCINOMA IDENTIFIED IN TOTAL
OF TWO OF 36 LYMPH NODES EXAMINED (2/36)

PATHOLOGIC TNM STAGE: BLADDER: pT3bN2MX
PROSTATE: pT2aN0MX (AJCC-1997)

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive urothelial carcinoma are submitted for p53 assay by immunohistology, results of which will issued in an addendum report.

SPECIMEN SOURCE:

- A: "Rt. ureter f/s"
- B: "Lt. distal ureter f/s"
- C: "Apical urethral margin"
- D: "Bladder/prostate"
- E: "Lt. L.N. of cloquet"
- F: "Lt. external iliac L.N."
- G: "Lt. obturator L.N."
- H: "Lt. hypogastric L.N."
- I: "Lt. common iliac L.N."
- J: "Rt. hypogastric L.N."
- K: "Rt. obturator L.N."
- L: "Rt. common iliac L.N."

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

M: "Rt presciatic L.N."

N: "Aortic bifurcation"

O: "Rt. proximal ureter"

P: "Left proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt. ureter f/s". It consists of a segment of ureter with periureteral soft tissue measuring 0.3 cm in length and 0.7 cm in diameter. The specimen is totally submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt. distal ureter f/s". It consists of a segment of ureter with periureteral soft tissue measuring 0.3 cm in length and 0.6 cm in diameter. The specimen is totally submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Apical urethral margin". It consists of a pink-tan irregular portion of tissue measuring 2.8 x 0.3 x 0.2 cm. Totally submitted for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labeled "Bladder/prostate". It consists of a cystoprostatectomy specimen measuring overall 15 x 11 x 6 cm. The posterior surface of the specimen is covered by peritoneum measuring 11 x 11.5 x 0.1 cm and shows a tan, firm, polypoid nodule in the lower portion of the retrovesical region measuring 2.5 x 1.3 x 0.7 cm. The peritoneum surrounding this region shows puckering and fibrosis. The rest of the peritoneal surface is unremarkable. The bladder itself measures 7 x 6.5 x 4.5 cm with palpable bulging nodules. The prostate measures 4.5 x 3.5 x 3.4 cm. The right seminal vesicle measures 3 x 1 x 0.8 cm, and the left seminal vesicle measures 2.8 x 1.5 x 0.8 cm. The outer surface of the bladder and prostate is inked black. Opening the specimen anteriorly reveals the prostatic urethra to measure 3 cm in length and 4.2 cm in circumference. The prostatic urethra is covered by pale tan glistening mucosa with no excavation. The verumontanum measures 0.5 x 0.4 x 0.3 cm. There is an ulcerated exophytic tan-brown necrotic mass covering the entire posterior wall and dome of the bladder measuring 6.5 x 5.5 x 2 cm. The tumor is seen involving the entire bladder wall with extension into perivesical fatty tissue up to peritoneal surface. The depth of invasion is approximately 2 cm. The rest of the bladder mucosa shows erythematous nodules varying in size from 0.3 to 0.6 cm. The uninvolved wall of the bladder is 0.9 cm in thickness and the involved wall is 2 cm in thickness. Both ureterovesical junctions are identified, patent and probed revealing the right ureter to be 5 cm in length and 1.5 cm in circumference, and the left 5 cm in length and 2 to 2.5 cm in circumference. The left ureter is more dilated compared to right, although both ureters are dilated. Both ureters are covered by pale tan glistening unremarkable mucosa. On serial sectioning, the prostate shows no definite malignancy. At the request of the surgeon, an intraoperative gross consultation is performed and the findings are discussed. Representative sections are submitted in 35 cassettes.

E: The specimen is received in formalin and labeled "Lt. L.N. of cloquet". It consists of a lymph node with fatty tissue measuring 1 x 1 x 0.3 cm overall. Totally submitted in one cassette.

F: The specimen is received in formalin and labeled "Lt. external iliac L.N.". It consists of lymph nodes with fibrofatty tissue measuring 2 x 1.5 x 0.8 cm overall. Totally submitted in one cassette.

[page 4 of 6]
Collected

Ordered by

Location

G: The specimen is received in formalin and labeled "Lt. obturator L.N.". It consists of lymph nodes with fibrofatty tissue measuring 5 x 3 x 1 cm overall. Totally submitted in two cassettes.

H: The specimen is received in formalin and labeled "Lt. hypogastric L.N.". It consists of lymph nodes with fibrofatty tissue measuring 1 x 1 x 0.3 cm overall. Totally submitted in one cassette.

I: The specimen is received in formalin and labeled "Lt. common iliac L.N.". It consists of fibrofatty tissue with lymph nodes measuring 1.1 x 0.6 x 0.3 overall. Totally submitted in one cassette.

J: The specimen is received in formalin and labeled "Rt. hypogastric L.N.". It consists of fibrofatty tissue with lymph nodes measuring 4 x 1 x 0.8 cm overall. Totally submitted in two cassettes.

K: The specimen is received in formalin and labeled "Rt. obturator L.N.". It consists of fibrofatty tissue with lymph nodes measuring 5 x 3 x 1 cm overall. Totally submitted in three cassettes.

L: The specimen is received in formalin and labeled "Rt. common iliac L.N.". It consists of fibrofatty tissue with lymph nodes measuring 3 x 2 x 1 cm overall. Totally submitted in one cassette.

M: The specimen is received in formalin and labeled "Rt. presciatic L.N.". It consists of fibrofatty tissue with lymph nodes measuring 1.5 x 1 x 0.3 cm overall. Totally submitted in one cassette.

N: The specimen is received in formalin and labeled "Aortic bifurcation", It consists of fibrofatty tissue with lymph nodes measuring 1.5 x 0.8 x 0.3 cm overall. Totally submitted in one cassette.

O: The specimen is received in formalin and labeled "Rt. proximal ureter". It consists of a segment of ureter with periureteral soft tissue measuring 3 cm in length and 0.6 cm in diameter. The specimen is received unoriented with two staples at one end. A representative section of the end with two staples is submitted in cassette O1 and the remaining tissue is submitted in cassette O2.

P: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of ureter with periureteral soft tissue measuring 1.8 cm in length and 0.9 cm in diameter. The specimen is received unoriented with two staples at one end. The specimen is serially sectioned and totally submitted in two cassettes.

SECTIONS:

AFS: frozen section, right ureter
BFS: frozen section, left distal ureter
CFS: frozen section, apical urethral margin
D1: bladder/prostate; serial section of peritoneal nodule
D2-12: tumor with deepest invasion and peritoneal surface
D13,14: trigone with proximal urethra
D15-18: erythematous bladder mucosa
D19: right distal prostate
D20: left distal prostate
D21: right mid distal prostate
D22: left mid distal prostate
D23: left mid anterior proximal prostate
D24,27: right mid proximal posterior prostate
D25: left mid proximal anterior prostate

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

Location:

D26,28: left mid proximal posterior prostate
D29: right proximal anterior prostate
D30: right seminal vesicle
D31: left seminal vesicle
D32,33: right perivesical lymph nodes
D34, 35: left perivesical lymph nodes
E: left lymph node of Cloquet - all embedded
F: left external iliac lymph nodes - all embedded
G1,2: left obturator lymph nodes - all embedded
H: left hypogastric lymph node - all embedded
I: left common iliac lymph nodes - all embedded
J1,2: right hypogastric lymph nodes - all embedded
K1-3: right obturator lymph nodes - all embedded
L: right common iliac lymph nodes - all embedded
M: right presciatic lymph node - all embedded
N: aortic bifurcation - all embedded
O1: right proximal ureter; end with two staples
O2: remaining tissue
P1: left proximal ureter; end with two staples
P2: remaining tissue

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right ureter:
- negative

BFS: Left distal ureter:
- negative

CFS: Apical urethral margin:
- negative

INTRAOPERATIVE GROSS CONSULTATION

Bladder/prostate (D):

- tumor identified, grossly extending through bladder wall

MICROSCOPIC EXAMINATION:

A-C: See final microscopic-diagnosis.

D: Sections of the bladder show a poorly differentiated urothelial carcinoma (D1-14,30,31), grades 3 and 4/4, exhibiting both squamoid and glandular features. The tumor extends through the bladder wall into perivesical soft tissue and to the subserosa of the peritoneum. Focal lymphovascular invasion is identified (D13). Resection margins are free of malignancy. Additional random sections of bladder mucosa show no evidence of urothelial carcinoma in situ (flat lesion) or high grade urothelial dysplasia.

Sections of the prostate show a focus of moderate to poorly differentiated prostatic adenocarcinoma (D21), Gleason's score 7 (4+3). This focus of carcinoma is unilateral being identified in the right mid to distal prostate and is confined within prostatic parenchyma without involvement of the capsule or periprostatic soft tissue. The prostatic urethra shows no evidence of urothelial dysplasia or urothelial malignancy. Resection margins are free of malignancy as are the bilateral seminal vesicles.

E-P: See final microscopic-diagnosis.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

Source: NCI Genomic Data Commons file ee04b970-dceb-48c4-a9ac-f659ae920d59 (TCGA-XF-AAN3.A0641D3F-1AB4-446B-B5AB-BB5882E82730.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).